Somatic mutation profile of tumor specimen TCGA-UY-A78N-01A (aliquot TCGA-UY-A78N-01A-12D-A339-08) from TCGA case TCGA-UY-A78N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.8 years (29,132 days).
Specimen TCGA-UY-A78N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fd4decd-849f-4a2a-af68-d0e76084c00e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A78N-10A (Blood Derived Normal), aliquot TCGA-UY-A78N-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fae9a6e8-8ac8-441e-be1c-4f64516f2c29

The open-access MAF lists 264 somatic variants for this specimen: 200 protein-altering or splice-affecting, 61 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 61, Nonsense Mutation 8, Frame Shift Del 6, In Frame Del 5, Splice Site 4, Frame Shift Ins 3, 5'UTR 1, Nonstop Mutation 1, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B9D2 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs750436680, COSV54683601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 144/222 reads (65%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCC9 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53962783; called by muse, mutect2, varscan2
- ABHD11 | c.779C>A p.T260K | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56105206; called by muse, mutect2, varscan2
- ACBD7 | c.255A>T p.K85N | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62252221; called by muse, mutect2, varscan2
- ACSS3 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV54085043; called by muse, mutect2, varscan2
- ADAMTS9 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as rs776836604, COSV55787594; called by muse, mutect2, varscan2
- ADGRF5 | c.2520T>G p.D840E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51929853; called by muse, mutect2, varscan2
- AKAP6 | c.1715C>T p.T572I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV55205123; called by muse, mutect2, varscan2
- ALG5 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53504436; called by muse, mutect2, varscan2
- ANGPTL4 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56844298; called by muse, mutect2, varscan2
- ANKMY2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61010968; called by muse, mutect2, varscan2
- ANO6 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV57656758; called by muse, mutect2, varscan2
- AP5B1 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); catalogued as COSV100375958; called by muse, mutect2, varscan2
- ARHGEF11 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59352423; called by muse, mutect2, varscan2
- ASH1L | c.4402A>T p.S1468C | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV64205486; called by muse, mutect2, varscan2
- ATP11B | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60026173; called by muse, mutect2, varscan2
- B4GALT7 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1435784513, COSV50352626; called by muse, mutect2, varscan2
- BATF2 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV57249447, COSV57250778; called by muse, mutect2, varscan2
- BMP5 | c.701T>A p.L234* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV100895847; called by muse, mutect2, varscan2
- CA11 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1386603410, COSV50032732; called by muse, mutect2, varscan2
- CARF | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770539703, COSV57546434; called by muse, mutect2, varscan2
- CC2D1B | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52558709; called by muse, mutect2, varscan2
- CCDC71 | c.1015_1047del p.W339_V349del | In Frame Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs758362347; called by mutect2, pindel
- CD1B | c.474G>C p.R158S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63803790; called by muse, mutect2, varscan2
- CD96 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51912783, COSV51924553; called by muse, mutect2, varscan2
- CDC45 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54243486; called by muse, mutect2, varscan2
- CDH22 | c.1663+1G>A p.X555_splice | Splice Site (SNP) | VAF 39/50 reads (78%) | catalogued as COSV64836486; called by muse, mutect2, varscan2
- CDHR3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV100488808, COSV58413788; called by muse, mutect2, varscan2
- CELSR2 | c.8065G>T p.A2689S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs946131796, COSV99603404, COSV99604408; called by muse, mutect2
- CENPT | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV54648166; called by muse, mutect2, varscan2
- CEP126 | c.2666T>A p.I889K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV54821729; called by muse, mutect2, varscan2
- CFAP221 | c.2062T>C p.Y688H | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54654005; called by muse, mutect2, varscan2
- CFAP77 | c.818G>C p.W273S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58007232; called by muse, mutect2, varscan2
- CHD4 | c.2053G>T p.E685* (on ENST00000357008 / NM_001363606.2; = p.E698* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV100537598; called by muse, mutect2, varscan2
- CIITA | c.1769A>G p.H590R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV60854078; called by muse, mutect2, varscan2
- CLVS1 | c.978-1G>T p.X326_splice | Splice Site (SNP) | VAF 44/95 reads (46%) | catalogued as COSV57970615; called by muse, mutect2, varscan2
- CR1 | c.4048T>A p.C1350S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1312864919, COSV65455894; called by muse, mutect2, varscan2
- CSF1R | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs139635308; called by muse, mutect2, varscan2
- CSMD2 | c.7335C>A p.Y2445* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99587848; called by muse, mutect2, varscan2
- CSPP1 | c.853G>T p.A285S (on ENST00000676605; = p.A244S on NM_024790.6) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.182); catalogued as COSV51580109, COSV51580211; called by muse, mutect2, varscan2
- CST9L | c.363_376del p.C122Qfs*66 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV65407544; called by mutect2, pindel, varscan2
- CUBN | c.7670G>T p.G2557V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64707903; called by muse, mutect2, varscan2
- CUL7 | c.2343G>C p.K781N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54813122; called by muse, varscan2
- DCANP1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.202); catalogued as rs377125441; called by muse, mutect2, varscan2
- DDX3X | c.1766+1G>T p.X589_splice (on ENST00000399959; = p.X590_splice on NM_001356.5) | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV67863087; called by muse, mutect2, varscan2
- DEFB135 | c.98T>G p.I33S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV66363411; called by muse, mutect2, varscan2
- DIAPH2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100230484, COSV61260565; called by muse, mutect2, varscan2
- DLEC1 | c.4423G>A p.G1475S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1271053107, COSV57295200; called by muse, mutect2, varscan2
- DLGAP5 | c.2305del p.E769Kfs*11 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as COSV55962003, COSV99903830; called by mutect2, pindel, varscan2
- DNAH9 | c.2423A>T p.K808I | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52334266; called by muse, mutect2, varscan2
- DNAJC28 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV58721219; called by muse, mutect2, varscan2
- DSC1 | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV57141848; called by muse, mutect2, varscan2
- EIF1B | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1235170046, COSV51762210; called by muse, mutect2, varscan2
- ENO3 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.083); catalogued as COSV56697225; called by muse, mutect2, varscan2
- EPS8 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55527626; called by muse, mutect2, varscan2
- EXD3 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV59803479, COSV59803867; called by muse, varscan2
- EXD3 | c.1964T>C p.L655P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59803524; called by muse, varscan2
- F13A1 | c.1964A>C p.N655T | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53553534; called by muse, mutect2, varscan2
- FAM117A | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV99544565, COSV99545168; called by muse, mutect2, varscan2
- FBXO30 | c.1709G>T p.C570F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV52790196; called by muse, mutect2, varscan2
- FER | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV55283120; called by muse, mutect2, varscan2
- FGFR3 | c.*129C>T | Splice Region (SNP) | VAF 26/61 reads (43%) | catalogued as COSV53391772; called by muse, mutect2, varscan2
- FHOD3 | c.2336A>T p.Q779L (on ENST00000359247 / NM_001281739.3; = p.Q796L on NM_025135.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV57164532; called by muse, mutect2, varscan2
- FOXN2 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs771387745, COSV61317041; called by muse, mutect2, varscan2
- FRMD4A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs749399377, COSV52714747, COSV52721827; called by muse, mutect2, varscan2
- GBP1 | c.1403A>C p.K468T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100976239; called by muse, mutect2, varscan2
- GCLM | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV64686720; called by muse, mutect2, varscan2
- GGA2 | c.461T>G p.M154R | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59167413; called by muse, mutect2, varscan2
- GPRASP1 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV64354807; called by muse, mutect2, varscan2
- HGD | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.028); catalogued as COSV52196036; called by muse, mutect2, varscan2
- HHIP | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.565); catalogued as rs769538924, COSV56836495; called by muse, mutect2, varscan2
- HHIP | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV56836517; called by muse, mutect2, varscan2
- HIPK1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.142); catalogued as rs1288928015, COSV61245986; called by muse, mutect2, varscan2
- HIPK3 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV57560877; called by muse, mutect2, varscan2
- HMCN1 | c.1951T>C p.F651L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54877468; called by muse, mutect2, varscan2
- HSPH1 | c.2446C>G p.P816A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV60710203; called by muse, mutect2, varscan2
- IFT46 | c.49A>G p.K17E (on ENST00000264021 / NM_001168618.2; = p.K68E on NM_020153.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs782348321, COSV99870952; called by muse, varscan2
- IGFBP6 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.986); catalogued as COSV56857007; called by muse, mutect2, varscan2
- IP6K2 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV53659684; called by muse, mutect2, varscan2
- IQCH | c.1844T>C p.V615A | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV60049172; called by muse, mutect2, varscan2
- ITGB6 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51790831; called by muse, mutect2, varscan2
- ITPKC | c.775_795del p.R259_G265del | In Frame Del (DEL) | VAF 17/59 reads (29%) | catalogued as COSV54573197; called by mutect2, pindel, varscan2
- KANK1 | c.1788A>C p.E596D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV63209597; called by muse, mutect2, varscan2
- KCNC1 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56391594; called by muse, mutect2, varscan2
- KCNJ11 | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100379023; called by muse, mutect2, varscan2
- KCNN4 | c.739A>T p.T247S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53454632; called by muse, mutect2, varscan2
- KCNQ5 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs577164847, COSV59649496; called by muse, mutect2, varscan2
- KIF4B | c.1951A>G p.M651V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV70527857; called by muse, mutect2, varscan2
- KIFBP | c.1661A>C p.Y554S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62831256; called by muse, mutect2, varscan2
- KMT5B | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as COSV58563836; called by muse, mutect2, varscan2
- KNSTRN | c.46A>C p.T16P | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1307486609, COSV51103482; called by muse, mutect2, varscan2
- KRTAP10-8 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs782110329, COSV58165939; called by muse, mutect2, varscan2
- LMCD1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs553073357, COSV50087243; called by muse, mutect2, varscan2
- LRP6 | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV53783372; called by muse, mutect2, varscan2
- LRRK2 | c.2767C>G p.Q923E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV54144134; called by muse, mutect2, varscan2
- LTF | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51605592; called by muse, mutect2, varscan2
- MAGI1 | c.3089T>A p.I1030N (on ENST00000402939 / NM_001033057.2; = p.I1059N on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58314605; called by muse, mutect2, varscan2
- MALSU1 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV54978169; called by muse, mutect2, varscan2
- MAN2A1 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54846374; called by muse, mutect2, varscan2
- MAPKBP1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52958223; called by muse, mutect2, varscan2
- MCU | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV64064661; called by muse, mutect2, varscan2
- MED12 | c.358T>G p.L120V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100376946; called by muse, mutect2, varscan2
- MMUT | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM012407, COSV51272332; called by muse, mutect2, varscan2
- MYH11 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1409062479, COSV55543045; called by muse, mutect2, varscan2
- NCBP3 | c.1816A>G p.I606V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV50106265; called by muse, mutect2, varscan2
- NCOA7 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV57652370; called by muse, mutect2
- NEB | c.8708A>G p.Q2903R | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV50811287; called by muse, mutect2, varscan2
- NEBL | c.2629A>G p.R877G | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV65801416; called by muse, mutect2, varscan2
- NLRP7 | c.2053A>G p.S685G (on ENST00000340844 / NM_206828.3; = p.S657G on NM_139176.3) | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV60171051; called by muse, mutect2, varscan2
- NOLC1 | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100893608; called by muse, mutect2
- NOS2 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as COSV58221814; called by muse, mutect2, varscan2
- NSG2 | c.479T>A p.I160N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57456715; called by muse, mutect2, varscan2
- NSUN2 | c.2104A>C p.M702L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52952534; called by muse, mutect2, varscan2
- NYAP1 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.48); catalogued as COSV100278401; called by muse, mutect2, varscan2
- OGDH | c.2893T>A p.Y965N | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV56045595; called by muse, mutect2, varscan2
- OSBPL7 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs1404551958, COSV50106622; called by muse, mutect2
- PAAF1 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs374237947, COSV60154534, COSV60155919; called by muse, mutect2, varscan2
- PAFAH1B1 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68209995; called by muse, mutect2, varscan2
- PAFAH1B2 | c.174A>G p.I58M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as COSV59166369; called by muse, mutect2, varscan2
- PARVB | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs780688321, COSV58683908; called by muse, mutect2, varscan2
- PCDH11X | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV53443136; called by muse, mutect2, varscan2
- PCDHA7 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1554134520, COSV100971338; called by muse, mutect2, varscan2
- PCDHA9 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782008951, COSV100969276; called by mutect2, varscan2
- PDHX | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760454961, COSV57164035; called by muse, mutect2, varscan2
- PLCB1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV62038498; called by muse, mutect2, varscan2
- PLXNA4 | c.5668A>G p.M1890V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV58105296; called by muse, mutect2, varscan2
- PNMA2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1044578124, COSV72908455; called by muse, mutect2, varscan2
- POT1 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 105/245 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62927983; called by muse, mutect2, varscan2
- PPARGC1A | c.1987A>T p.K663* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV99337621; called by muse, mutect2, varscan2
- PRDX4 | c.417A>T p.R139S | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs768534120, COSV65018513; called by muse, mutect2, varscan2
- PRODH2 | c.436C>T p.R146W (on ENST00000301175; = p.R70W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs755061585, COSV56558344; called by muse, mutect2, varscan2
- PRPS1L1 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV72649812; called by muse, mutect2, varscan2
- PSMD7 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV54696999; called by muse, mutect2, varscan2
- PTPRN | c.2564A>C p.Y855S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55345570; called by muse, mutect2, varscan2
- PWWP3B | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs752396438, COSV61798309; called by muse, varscan2
- PXDNL | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62478201; called by muse, mutect2, varscan2
- RAD54L2 | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56577009; called by muse, mutect2, varscan2
- RASSF4 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as COSV58484277, COSV58484514; called by muse, mutect2, varscan2
- RBM39 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV53613791; called by muse, mutect2, varscan2
- REST | c.3271G>T p.E1091* | Nonsense Mutation (SNP) | VAF 40/56 reads (71%) | catalogued as COSV100470814; called by muse, mutect2, varscan2
- RET | c.2992T>C p.F998L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60686963; called by muse, mutect2, varscan2
- REV1 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51481818; called by muse, mutect2, varscan2
- RPN2 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52903761; called by muse, mutect2, varscan2
- SF3B1 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.573); catalogued as COSV59206630; called by muse, mutect2, varscan2
- SIX5 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52175537; called by muse, mutect2, varscan2
- SLC10A5 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV72828220; called by muse, mutect2, varscan2
- SLC13A5 | c.836T>A p.F279Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV53421653; called by muse, mutect2, varscan2
- SLC36A4 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | catalogued as COSV58395225; called by muse, mutect2, varscan2
- SLC37A3 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58262801; called by muse, mutect2, varscan2
- SLC4A1AP | c.1170T>G p.D390E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.124); catalogued as COSV58133637; called by muse, mutect2, varscan2
- SLC52A2 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV57350720; called by muse, mutect2, varscan2
- SLC7A8 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs750096654, COSV57553025; called by muse, mutect2, varscan2
- SLITRK5 | c.11G>C p.C4S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV61521027; called by muse, mutect2, varscan2
- SORCS2 | c.2790C>A p.D930E | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61163221; called by muse, mutect2, varscan2
- SPOCK1 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56436920, COSV56445528; called by muse, varscan2
- SRGAP2 | c.2444C>T p.A815V (on ENST00000624873 / NM_001170637.4; = p.A816V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs372717466; called by muse, mutect2, varscan2
- SSRP1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV53480567; called by muse, mutect2, varscan2
- STIM1 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56151585; called by muse, mutect2, varscan2
- SUPT6H | c.4235T>C p.V1412A | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100112235; called by muse, mutect2, varscan2
- TDRD1 | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770791214, COSV52587450; called by muse, mutect2, varscan2
- TET1 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65382049, COSV65384136; called by muse, mutect2, varscan2
- TEX2 | c.1655A>C p.N552T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51977452; called by muse, mutect2, varscan2
- TICRR | c.2494C>G p.R832G | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV51537897, COSV51540775; called by muse, mutect2, varscan2
- TIGD4 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as COSV58548985; called by muse, mutect2, varscan2
- TMEM245 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV65821885; called by muse, mutect2, varscan2
- TMPRSS11E | c.479T>G p.V160G | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.505); catalogued as COSV59517929; called by muse, mutect2, varscan2
- TNKS2 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV65414675; called by muse, mutect2, varscan2
- TPP2 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV65751012; called by muse, mutect2, varscan2
- TRANK1 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV57140671; called by muse, mutect2, varscan2
- TUBA1C | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56509348; called by muse, varscan2
- UBE4B | c.2939C>T p.T980I (on ENST00000343090 / NM_001105562.3; = p.T851I on NM_006048.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53527208; called by muse, mutect2, varscan2
- UCHL5 | c.92A>C p.Q31P | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66485676; called by muse, mutect2, varscan2
- ULK1 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as COSV100416646; called by muse, mutect2, varscan2
- VCAN | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147551428; called by muse, mutect2, varscan2
- WDR36 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV72605060; called by muse, mutect2, varscan2
- XAB2 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV64321160; called by muse, mutect2, varscan2
- ZBTB1 | c.1450A>G p.T484A | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV62437253; called by muse, mutect2, varscan2
- ZDHHC8 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV57708910; called by muse, mutect2, varscan2
- ZEB1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV58036559; called by muse, mutect2, varscan2
- ZHX3 | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV58380677; called by muse, mutect2
- ZMIZ1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.96); catalogued as COSV57889780; called by mutect2, varscan2
- ZNF106 | c.4433C>A p.T1478N | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55513748; called by muse, mutect2, varscan2
- ZNF148 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV62302261; called by muse, mutect2, varscan2
- ZNF160 | c.1817C>T p.S606L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV61998925; called by muse, mutect2, varscan2
- ZNF232 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.228); catalogued as COSV51502443; called by muse, mutect2, varscan2
- ZNF485 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62423659; called by muse, mutect2, varscan2
- ZNF569 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 65/113 reads (58%) | catalogued as COSV100386372; called by muse, mutect2, varscan2
- ZNF85 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV60213343, COSV60214269; called by muse, mutect2, varscan2
- AMOTL2 | c.1135_1174del p.K379Gfs*175 | Frame Shift Del (DEL) | VAF 118/398 reads (30%) | called by mutect2, pindel
- BCL9 | c.2056_2064del p.L686_P688del | In Frame Del (DEL) | VAF 19/44 reads (43%) | called by mutect2, pindel, varscan2
- EFCC1 | c.1797_*22del | Nonstop Mutation (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- KDM6A | c.3461_3468delinsTG p.S1154_N1156delinsL | In Frame Del (DEL) | VAF 23/31 reads (74%) | called by pindel, varscan2*
- MON2 | c.1698_1701del p.L567Ffs*15 | Frame Shift Del (DEL) | VAF 79/133 reads (59%) | called by mutect2, pindel, varscan2
- PPP2R1A | c.553_561del p.A185_S187del | In Frame Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel*, varscan2
- RAPGEF3 | c.1881dup p.E628* (on ENST00000389212; = p.E586* on NM_006105.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 30/118 reads (25%) | called by mutect2, pindel, varscan2
- STYXL1 | c.495_504dup p.F169Rfs*13 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, varscan2
- ZC3H12A | c.1038dup p.R347Qfs*26 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- ZNF451 | c.1957del p.R653Dfs*11 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- A2ML1 | c.2994C>T p.I998= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV55285746; called by muse, mutect2, varscan2
- ACER3 | c.792C>T p.L264= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV53596950; called by muse, mutect2, varscan2
- AFF1 | c.2856A>G p.P952= | Silent (SNP) | VAF 50/66 reads (76%) | catalogued as rs757294859, COSV57116686; called by muse, mutect2, varscan2
- AGGF1 | c.138C>T p.I46= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV57227758; called by muse, mutect2, varscan2
- AQP2 | c.258C>T p.A86= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs780540045, COSV52228921; ClinVar: likely benign; called by muse, mutect2, varscan2
- BPIFA1 | c.117C>T p.A39= | Silent (SNP) | VAF 40/402 reads (10%) | catalogued as COSV62823880; called by muse, mutect2
- BRPF1 | c.1113T>A p.I371= | Silent (SNP) | VAF 54/237 reads (23%) | catalogued as COSV57403184; called by muse, mutect2, varscan2
- CFAP91 | c.621A>G p.A207= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as COSV56339131; called by muse, mutect2, varscan2
- CILK1 | c.207C>A p.I69= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV63153394; called by mutect2, varscan2
- CMAS | c.315T>A p.G105= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV57555981; called by muse, mutect2, varscan2
- CRYBG1 | c.5655T>C p.C1885= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as COSV64810548; called by muse, mutect2, varscan2
- DGKE | c.228G>A p.V76= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV52348885; called by muse, mutect2, varscan2
- DST | c.22338C>G p.P7446= (on ENST00000361203 / NM_001374722.1; = p.P5156= on NM_015548.5) | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV54997931; called by muse, mutect2, varscan2
- DYNC1H1 | c.9216G>T p.S3072= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV64134382; called by muse, mutect2, varscan2
- ELOVL3 | c.27T>C p.H9= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV64174123; called by muse, mutect2, varscan2
- F10 | c.987G>A p.K329= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as COSV65020779; called by muse, mutect2, varscan2
- F12 | c.852G>A p.R284= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1053549256, COSV99499538; called by muse, mutect2, varscan2
- FANCM | c.2805T>C p.S935= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1049679142, COSV57497330; ClinVar: likely benign; called by muse, mutect2, varscan2
- FILIP1 | c.465G>A p.E155= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV52722989; called by muse, mutect2, varscan2
- GEMIN2 | c.82C>T p.L28= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV51627250; called by muse, mutect2
- GRHPR | c.420G>T p.S140= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV58941289; called by muse, mutect2, varscan2
- HEPHL1 | c.1887T>C p.Y629= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs755266084, COSV59889492; called by muse, mutect2, varscan2
- HJV | c.726T>C p.N242= (on ENST00000336751 / NM_213653.4; = p.N129= on NM_145277.5) | Silent (SNP) | VAF 69/114 reads (61%) | catalogued as COSV60951139; called by muse, mutect2, varscan2
- HRH4 | c.150T>C p.S50= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as COSV56927257; called by muse, mutect2, varscan2
- HTR6 | c.201G>A p.S67= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57032042; called by muse, mutect2
- KCNN4 | c.78C>G p.A26= | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as COSV53454643; called by muse, mutect2, varscan2
- KRT27 | c.873T>C p.S291= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV56970769; called by muse, mutect2, varscan2
- LRRC7 | c.762T>C p.N254= (on ENST00000651989 / NM_001370785.2; = p.N221= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV50411225; called by muse, mutect2, varscan2
- MAP1A | c.8115G>A p.K2705= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as COSV55806135; called by muse, mutect2, varscan2
- MON1B | c.1422G>A p.E474= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV50245363; called by muse, mutect2, varscan2
- MUC15 | c.52C>T p.L18= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV55552841; called by muse, mutect2, varscan2
- MYBBP1A | c.2793C>T p.L931= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as rs1448612983, COSV54593650; called by muse, mutect2, varscan2
- NKX2-2 | c.18A>G p.T6= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV65819168; called by muse, mutect2, varscan2
- NUMA1 | c.5578C>T p.L1860= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV52619772; called by muse, mutect2, varscan2
- PCDHB8 | c.1080T>C p.N360= | Silent (SNP) | VAF 43/410 reads (10%) | catalogued as rs782707210, COSV50847707; called by muse, mutect2, varscan2
- PCDHGB3 | c.1785C>T p.D595= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV53899358; called by muse, mutect2, varscan2
- PDP1 | c.867T>C p.T289= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV52600166; called by muse, mutect2, varscan2
- PDXDC1 | c.1563G>A p.G521= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs1410298481, COSV100363030; called by muse, mutect2, varscan2
- PITX1 | c.489G>A p.Q163= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV54761536; called by muse, mutect2, varscan2
- RBM5 | c.1584G>A p.K528= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV61736519; called by muse, mutect2, varscan2
- RLBP1 | c.210G>A p.V70= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV51527239; called by muse, mutect2, varscan2
- RPGRIP1 | c.1444T>C p.L482= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV52844778; called by muse, mutect2, varscan2
- S100PBP | c.501G>A p.S167= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs12092326; called by muse, mutect2, varscan2
- SEMA5B | c.1443T>C p.A481= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99531223; called by muse, mutect2
- SETD1A | c.3324G>A p.L1108= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs762162678, COSV52685027; called by muse, mutect2, varscan2
- SIX5 | c.648C>T p.L216= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV52177155, COSV99352912; called by muse, mutect2, varscan2
- SLC17A6 | c.1620C>A p.T540= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV54133479; called by muse, mutect2, varscan2
- SLC25A38 | c.663C>T p.F221= | Silent (SNP) | VAF 117/286 reads (41%) | catalogued as COSV56193716; called by muse, mutect2, varscan2
- SPINK4 | c.81A>G p.G27= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV65687798; called by muse, mutect2, varscan2
- TBC1D31 | c.2733A>G p.L911= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs370977650; called by muse, mutect2, varscan2
- TFRC | c.198C>T p.I66= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as rs761390479, COSV64053843; called by muse, mutect2, varscan2
- TMEM181 | c.1116C>T p.Y372= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV65562068; called by muse, mutect2, varscan2
- TRPV2 | c.24A>T p.P8= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs760606289, COSV58427261; called by muse, mutect2, varscan2
- TST | c.60C>T p.I20= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99968168; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3972C>T p.I1324= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV51952749; called by muse, mutect2, varscan2
- UNC93B1 | c.321C>A p.I107= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV57097839; called by muse, mutect2, varscan2
- USP54 | c.2775A>G p.S925= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs906081257, COSV60439717; called by muse, mutect2, varscan2
- WDR6 | c.1947C>T p.H649= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV58243974; called by muse, mutect2, varscan2
- WDR92 | c.924A>G p.A308= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs1446234297, COSV54560445; called by muse, mutect2, varscan2
- ZNF43 | c.1632C>G p.G544= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV61682766; called by muse, varscan2
- ZNF574 | c.114C>T p.H38= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs201349900; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622575 T>A | 3'Flank (SNP) | VAF 165/335 reads (49%) | catalogued as COSV57541225; called by muse, mutect2, varscan2
- PPT1 | c.-1G>A | 5'UTR (SNP) | VAF 67/91 reads (74%) | catalogued as COSV100858372; called by muse, mutect2, varscan2
- RPP38 | chr10:15096490 G>T | 5'Flank (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
